Surgical pathology report (de-identified scan), TCGA case TCGA-LI-A67I, project TCGA-SARC (Sarcoma), tissue source site Hartford Hospital, specimen TCGA-LI-A67I-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:	LOCATION:
DATE RECEIVED:	SUBMITTING MD:
DATE REPORTED:	CC:

DIAGNOSIS

#1 SOFT TISSUE TUMOR, RIGHT THIGH, RESECTION:

Tumor type (WHO):	Myxofibrosarcoma (so-called "myxoid MFH")
Histologic grade (FNCLCC):	Grade 3 (Tumor differentiation: 3, mitosis count: 3, tumor necrosis: 2)
Tumor size:	20 cm
Tumor depth:	Deep fascial extension
Necrosis:	15-20%
Mitoses:	Range of 10-30 per 10 HPF
Margins:	Positive proximal margin (specimen #2), close posterior margin (less than 1 mm).
Ancillary studies:	N/A
Lymphovascular Invasion:	Not identified.
Lymph nodes:	Two incidental negative lymph nodes (0/2)
Prior Treatment:	No
Treatment Effect:	N/A
AJCC stage:	pT2b

#2 SOFT TISSUE, MOST PROXIMAL MARGIN, EXCISION: TUMOR IS PRESENT AT THE PROXIMAL RESECTION MARGIN.

Electronically Signed Out

COMMENT

Sections show mainly a high-grade (grade 3) sarcoma with pleomorphic and storiform features. There are foci of lower grade areas with curvilinear capillaries and myxoid change which is reminiscent of "myxofibrosarcoma". Focally the cells are rhabdoid appearing and note is made of IHC stains on prior core biopsy with negative myogenin.

Clinical Diagnosis and History:

Right thigh sarcoma

Tissue(s) Submitted:

- 1: RIGHT THIGH SARCOMA
- 2: MOST PROXIMAL MARGIN

Gross Description:

Specimen #1 is received in formalin and labeled right thigh sarcoma and consists of a 3,550 gram tissue resection measuring 32 x 23 x 13 cm with an attached overlying ellipse of skin measuring 39 x 5.5 cm with a central suture. The specimen is designated per

ICD-O-3
Fibrous histiocytoma malignant 8830/3
Site: Connective, subcutaneous and other
soft tissues of thigh C49.2
JW 5/10/13

Case is (re):		

[page 2 of 2]
Surgical Pathology Report

surgeon as follows: long suture-proximal. The specimen is inked blue-lateral, green-medial and black-deep. The deep surface is focally covered by muscle but largely covered by deep fascia. Sectioning reveals a 20 x 15 cm partially circumscribed white firm mass with areas of hemorrhage and necrosis (percent necrosis approximately 40%). The mass appears to be pushing the borders and appears to be infiltrative. However, positivity cannot grossly be assessed. The mass is closest to the deep margin less than 1 mm. Pictures were taken. Representative sections are as follows:

1A-1V: tumor to margins

1W-1BB: representative sections of the tumor.

Specimen #2 is received in formalin and labeled most proximal margin and consists of a 5.0 x 1.9 x 1.2 cm firm, irregular soft tissue specimen with a cut surface. The non-cut surface is inked blue. Representative sections are as follows:

2A: representative cut surface (thinned)

2B: perpendicular sections of the non-cut surface.

Source: NCI Genomic Data Commons file ee69eb3a-a229-4986-a0c4-d0340b42f241 (TCGA-LI-A67I.2071BA13-E5BA-4D76-A5A1-B7DB724AA9DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).